CCDI case PBBZLB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/49d38a30-2e99-45e2-9f27-95bc5714307e

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.3 years (1,938 days).

Biospecimens (3 samples)
- Sample 0DLIF4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLIFB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLIFS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
